Somatic mutation profile of tumor specimen TCGA-B0-4945-01A (aliquot TCGA-B0-4945-01A-01D-1421-08) from TCGA case TCGA-B0-4945, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.4 years (27,523 days).
Specimen TCGA-B0-4945-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6797817-719c-44ea-a5aa-e28291e880db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4945-11A (Solid Tissue Normal), aliquot TCGA-B0-4945-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25d7c657-7a7c-4c4d-ae19-021adfe7890d

The open-access MAF lists 38 somatic variants for this specimen: 36 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 29, Frame Shift Del 4, Silent 2, Splice Site 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 18/62 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131690962, CM003060, COSV104374386, COSV56542402, COSV56545166; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.2129C>A p.S710Y | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54386878; called by muse, mutect2, varscan2
- ARHGAP32 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 107/480 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV59844279; called by muse, mutect2, varscan2
- ATP5MPL | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV54602695; called by muse, mutect2, varscan2
- CDC6 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 7/149 reads (5%) | catalogued as COSV52929923; called by muse, mutect2
- CDKN2AIP | c.1413del p.I471Mfs*4 | Frame Shift Del (DEL) | VAF 37/249 reads (15%) | catalogued as COSV56628007; called by mutect2, pindel, varscan2
- COG5 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV51744342; called by muse, mutect2, varscan2
- DAXX | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs767991311, COSV56467230; called by muse, mutect2, varscan2
- DCDC1 | c.3846G>C p.K1282N (on ENST00000597505 / NM_001367979.1; = p.K389N on NM_020869.3) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100338021, COSV100338830, COSV57997887; called by muse, mutect2, varscan2
- DNAJC9 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54350298; called by muse, mutect2
- FCHSD1 | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV71300572; called by muse, mutect2, varscan2
- FCRL5 | c.2245G>T p.V749L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV62512411; called by muse, varscan2
- GALNT5 | c.2790A>T p.Q930H | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52036287; called by muse, mutect2, varscan2
- GRM2 | c.2096T>A p.V699E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV56583525; called by muse, varscan2
- HSPA5 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52334291; called by muse, mutect2, varscan2
- INSRR | c.942-2A>G p.X314_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV63871431; called by muse, mutect2, varscan2
- ITPKB | c.2031A>G p.A677= | Splice Region (SNP) | VAF 23/198 reads (12%) | catalogued as COSV55258241; called by muse, mutect2, varscan2
- KMT2C | c.6488C>A p.P2163H | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51386021; called by muse, mutect2, varscan2
- KNL1 | c.45A>G p.I15M | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV61152082; called by muse, mutect2
- LIMK2 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59181646; called by muse, mutect2, varscan2
- MAP3K15 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100134885; called by muse, mutect2
- MPP3 | c.688T>A p.F230I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV68197665; called by muse, mutect2
- OR12D3 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs757821014, COSV65826733; called by muse, mutect2
- OTOP1 | c.1415T>G p.M472R | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV56391329; called by muse, mutect2, varscan2
- PTGIR | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV52191624; called by muse, mutect2, varscan2
- RIC8B | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV62693567; called by muse, mutect2, varscan2
- SLC7A3 | c.877T>G p.S293A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53226808; called by muse, mutect2, varscan2
- SMC3 | c.540A>T p.K180N | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV62419293; called by muse, mutect2, varscan2
- SRSF7 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57446533; called by muse, mutect2, varscan2
- TMEM132D | c.2415C>A p.N805K | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV67159198; called by muse, mutect2, varscan2
- UBA2 | c.1778A>C p.D593A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55827534; called by muse, mutect2, varscan2
- VPS50 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.482); catalogued as COSV58506152; called by muse, mutect2, varscan2
- WDR46 | c.544A>C p.I182L | Missense Mutation (SNP) | VAF 119/705 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV65842027, COSV65842311; called by muse, mutect2, varscan2
- ARID1A | c.3414_3417del p.G1139Lfs*21 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- SEC31A | c.227del p.P76Lfs*14 | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | called by pindel, varscan2
- ZFHX4 | c.7818del p.K2606Nfs*3 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- AGAP6 | c.1545C>T p.D515= (on ENST00000374056 / NM_001365867.1; = p.D538= on NM_001077665.2) | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as COSV65017380; called by muse, mutect2, varscan2
- TCF3 | c.531G>A p.P177= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs199702817, COSV53646401, COSV53648708; called by mutect2, varscan2
